Somatic mutation profile of tumor specimen TCGA-HC-7744-01A (aliquot TCGA-HC-7744-01A-11D-2114-08) from TCGA case TCGA-HC-7744, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 46.7 years (17,065 days).
Specimen TCGA-HC-7744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83a9e83f-d744-44e2-a784-65a973370bcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7744-10A (Blood Derived Normal), aliquot TCGA-HC-7744-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/343fbc1b-2666-4a31-a08e-8411dc98d215

The open-access MAF lists 25 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 22, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1B | c.1009A>G p.K337E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57775926, COSV57776460; called by muse, mutect2, varscan2
- BRWD1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 64/98 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58122445; called by muse, varscan2
- CERK | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs1401180229, COSV53450563; called by muse, mutect2, varscan2
- EHBP1L1 | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV58572024; called by mutect2, varscan2
- EPS8L3 | c.515T>C p.M172T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62609046; called by muse, mutect2, varscan2
- FBN2 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52503031; called by muse, mutect2, varscan2
- GRXCR2 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs376301264; called by muse, mutect2, varscan2
- GTDC1 | c.1109A>T p.H370L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53991131, COSV54003001; called by muse, mutect2, varscan2
- KRTAP13-4 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs558455896, COSV61878842; called by muse, mutect2, varscan2
- MAPKAPK5 | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV73436065; called by muse, mutect2, varscan2
- PCDH11X | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 67/83 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53452913; called by muse, mutect2, varscan2
- PIKFYVE | c.4850A>C p.Q1617P | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV52238907; called by muse, mutect2, varscan2
- PSD2 | c.800A>C p.D267A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV51197766; called by muse, mutect2, varscan2
- RIMBP3 | c.4196G>A p.R1399K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs1256585460; called by muse, mutect2, varscan2
- SEL1L3 | c.2237A>G p.N746S | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53538148; called by muse, mutect2
- SLC30A10 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV63070770; called by muse, mutect2, varscan2
- SPG11 | c.6092G>A p.R2031Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1365555358, COSV55992535; called by muse, mutect2, varscan2
- SPTA1 | c.3958G>C p.D1320H | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63750801; called by muse, mutect2
- TRIT1 | c.430A>T p.T144S | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1430106590, COSV57547602; called by muse, varscan2
- TSTD2 | c.370A>G p.S124G | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1240064226, COSV57845280; called by muse, mutect2, varscan2
- VANGL2 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.854); catalogued as rs1197533506, COSV63604211; called by muse, mutect2, varscan2
- XPC | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.037); catalogued as COSV53204168, COSV53204741; called by muse, mutect2
- NCOR1 | c.4968dup p.N1657Qfs*57 | Frame Shift Ins (INS) | VAF 67/235 reads (29%) | called by mutect2, pindel, varscan2
- CCT2 | c.780T>C p.S260= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs201962311, COSV54739578; called by muse, mutect2, varscan2
- DIP2A | c.3933G>A p.T1311= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs776259531; called by muse, varscan2
